FM case AD14983 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/81660e9d-f0e4-46a4-831f-2ed19bff0f12

Female, 64.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Tumor.
